Gene-level copy-number profile of tumor specimen TCGA-L5-A4OR-01A from TCGA case TCGA-L5-A4OR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 83.3 years (30,417 days).
Specimen TCGA-L5-A4OR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.eb99f685-ef5a-4fc7-9ef7-5aa56be631d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OR-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/81ff7865-20f1-49ad-8f59-7c48d38b1221

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 868; copy number 2: 10,055; copy number 3: 19,369; copy number 4: 18,322; copy number 5: 7,359; copy number 6: 2,178; copy number 7: 397; copy number 8: 605; copy number 9: 222; copy number 10: 132; copy number 11: 2; copy number 12: 75; copy number 13: 32; copy number 14: 101; copy number 16: 47; copy number 17: 28; copy number 32: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OR-01A-11D-A25X-01): tumor purity 0.62, ploidy 3.85, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,534,374–78,553,296, 2 genes: AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,651 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,472,288–10,796,650, 5 genes, copy number 9 (within-gene range 1–9): PEX14, AL139423.2, RN7SL614P, CASZ1, AL139423.1.
- chr1:23,380,909–24,008,519, 25 genes, copy number 7 (within-gene range 3–7): TCEA3, AL357134.1, ASAP3, E2F2, AL021154.1, ID3, AL450043.1, MDS2, AL451000.1, RPL11, ELOA-AS1, ELOA, PITHD1, LYPLA2, GALE, HMGCL, FUCA1, CNR2, BTBD6P1, AL590609.2, MIR378F, H3P1, PNRC2, SRSF10, AL590609.1.
- chr1:24,415,802–24,970,865, 15 genes, copy number 8: NIPAL3, RCAN3AS, RCAN3, NCMAP-DT, NCMAP, AL445686.1, Y_RNA, SRRM1, AL445648.1, CLIC4, RNU6-1208P, RUNX3, MIR6731, RUNX3-AS1, AL445471.1.
- chr3:170,418,868–170,860,380, 1 gene, copy number 8 (within-gene range 5–8): AC026316.4.
- chr3:170,448,639–175,810,548, 56 genes, copy number 8 (within-gene range 5–8): SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2, TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3.
- chr5:58,198–45,895,970, 710 genes, copy number 7–9 (broad region; genes not listed).
- chr7:7,102,573–17,558,909, 116 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:43,112,629–43,566,001, 1 gene, copy number 7 (within-gene range 6–7): HECW1.
- chr7:43,508,728–47,948,466, 105 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:51,016,212–54,938,184, 43 genes, copy number 7–8 (within-gene range 6–8): COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1.
- chr7:112,520,488–112,521,670, 1 gene, copy number 8: NPM1P14.
- chr10:32,267,751–32,378,798, 1 gene, copy number 14 (within-gene range 6–14): EPC1.
- chr10:32,346,499–36,089,389, 57 genes, copy number 9–14: AL391839.2, AL391839.1, RNU6-1244P, AL391839.3, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, AL353600.2, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1.
- chr15:87,576,929–90,717,141, 104 genes, copy number 10 (broad region; genes not listed).
- chr15:91,408,708–101,170,821, 190 genes, copy number 8–32 (within-gene range 4–32) (broad region; genes not listed).
- chr18:47,390–2,049,510, 46 genes, copy number 16 (within-gene range 5–16): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr18:1,927,727–1,929,094, 1 gene, copy number 16: AIDAP3.
- chr18:3,496,032–4,455,307, 1 gene, copy number 9 (within-gene range 5–9): DLGAP1.
- chr18:3,770,017–5,004,537, 10 genes, copy number 9 (within-gene range 6–9): AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1.
- chr18:6,601,540–6,642,478, 2 genes, copy number 11: RN7SL282P, AP005205.1.
- chr18:7,566,782–9,020,764, 24 genes, copy number 10 (within-gene range 4–10): PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19.
- chr18:20,946,906–28,177,946, 137 genes, copy number 8–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 864. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
